Somatic mutation profile of tumor specimen TCGA-BJ-A2P4-01A (aliquot TCGA-BJ-A2P4-01A-11D-A18F-08) from TCGA case TCGA-BJ-A2P4, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 29.0 years (10,602 days).
Specimen TCGA-BJ-A2P4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d2e0713-379d-4619-9068-bc7421d9e0c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A2P4-10A (Blood Derived Normal), aliquot TCGA-BJ-A2P4-10A-01D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b57c82a7-73ce-4a1b-bfa3-5cae96a2244b

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, In Frame Del 1, Frame Shift Ins 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 37/96 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AP3B1 | c.1376C>G p.A459G | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV54887918; called by muse, mutect2, varscan2
- GPRIN2 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 12/70 reads (17%) | catalogued as rs782417886, COSV65401680; called by muse, mutect2, varscan2
- LCT | c.2396G>A p.R799H | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.94); catalogued as rs565990613, COSV51552443, COSV51553501; called by muse, mutect2, varscan2
- MUC17 | c.4769C>A p.A1590D | Missense Mutation (SNP) | VAF 86/258 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV60295703; called by muse, varscan2
- SLA | c.225A>G p.I75M (on ENST00000338087 / NM_001045556.3; = p.I115M on NM_006748.4) | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV55085507; called by muse, mutect2, varscan2
- UNC79 | c.3883G>A p.A1295T (on ENST00000393151 / NM_001346218.2; = p.A1118T on NM_020818.5) | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.946); catalogued as rs1047896978, COSV56380985; called by muse, mutect2, varscan2
- ANKLE1 | c.1271del p.L424Pfs*39 (on ENST00000394458; = p.L370Pfs*39 on NM_152363.6) | Frame Shift Del (DEL) | VAF 17/59 reads (29%) | called by mutect2, pindel, varscan2
- MYMK | c.534_535insC p.V179Rfs*52 | Frame Shift Ins (INS) | VAF 11/52 reads (21%) | called by mutect2, pindel*, varscan2
- POLR1B | c.2761_2763del p.P921del | In Frame Del (DEL) | VAF 30/111 reads (27%) | called by mutect2, pindel, varscan2
- DDX27 | c.891C>T p.P297= | Silent (SNP) | VAF 48/93 reads (52%) | catalogued as rs200539083, COSV65630394; called by muse, mutect2, varscan2
- PRODH2 | c.657G>A p.R219= (on ENST00000301175; = p.R143= on NM_021232.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV56560784; called by muse, mutect2, varscan2
- SF3B3 | c.726A>T p.S242= | Silent (SNP) | VAF 107/262 reads (41%) | catalogued as COSV56789342; called by muse, mutect2, varscan2
